Somatic mutation profile of tumor specimen 0DLRHW from CCDI case PBBZNV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,810 days).
Specimen 0DLRHW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac676b02-a653-4cad-95a6-9c52f229866b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28e68d19-5d5e-43c6-ad82-f737c44ad663

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 200/1159 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP5B1 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 105/646 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1019532967; called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 27/876 reads (3%) | called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
- ZAN | c.-100G>C | 5'UTR (SNP) | VAF 5/40 reads (13%) | catalogued as COSV61815815; called by muse, mutect2
